Gene-level copy-number profile of specimen HCM-SANG-1307-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-1307-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G1.
Specimen HCM-SANG-1307-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d5717dd5-c5f3-4857-b5de-21314ba4cfb8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1307-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/1c439c73-a0f2-4eb0-9b52-cc056f3eef45

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1,350; copy number 2: 11,666; copy number 3: 31,571; copy number 4: 12,819; copy number 5: 522; copy number 6: 39; copy number 7: 309; copy number 8: 13; copy number 10: 4; copy number 11: 77; copy number 12: 4; copy number 13: 14; copy number 14: 8.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,214,672, 9 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 429 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:52,390,515–54,365,634, 12 genes, copy number 8–14: LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1.
- chr19:31,520,155–36,152,449, 198 genes, copy number 7–11 (broad region; genes not listed).
- chr19:36,604,817–39,255,269, 116 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:39,328,353–41,128,381, 103 genes, copy number 7–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
